Somatic mutation profile of tumor specimen TCGA-51-4079-01A (aliquot TCGA-51-4079-01A-01D-1458-08) from TCGA case TCGA-51-4079, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.6 years (26,899 days).
Specimen TCGA-51-4079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e8f4e3f-6ba9-4373-9d59-eca98a679c21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-51-4079-11A (Solid Tissue Normal), aliquot TCGA-51-4079-11A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/890d59b6-83f9-4b9e-820a-c2098e826604

The open-access MAF lists 441 somatic variants for this specimen: 333 protein-altering or splice-affecting, 87 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 87, Nonsense Mutation 26, Frame Shift Del 17, Intron 11, Frame Shift Ins 5, 3'UTR 4, Splice Site 3, RNA 3, 5'UTR 2, Splice Region 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EHMT1 | c.3502C>T p.R1168* | Nonsense Mutation (SNP) | VAF 76/239 reads (32%) | catalogued as rs121918301, CM062590, COSV71777957; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 26/128 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 52/207 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TSC1 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 19/296 reads (6%) | catalogued as rs781371665, COSV53768589; ClinVar: pathogenic; called by muse, mutect2
- ABCA2 | c.946G>A p.E316K (on ENST00000614293; = p.E286K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV55797034; called by muse, mutect2, varscan2
- ABCB5 | c.2203T>A p.Y735N (on ENST00000404938 / NM_001163941.2; = p.Y290N on NM_178559.6) | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV51712613; called by muse, mutect2, varscan2
- ABCC9 | c.3817G>A p.E1273K | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53976080; called by muse, mutect2, varscan2
- ABI3BP | c.1157C>G p.S386* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | catalogued as COSV52540633; called by muse, mutect2
- AC004922.1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as COSV53557653; called by muse, mutect2
- AC013489.1 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV51552010; called by muse, mutect2, varscan2
- ACOT8 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54170151; called by muse, mutect2, varscan2
- ACSM5 | c.1181A>T p.K394M | Missense Mutation (SNP) | VAF 84/357 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV59372668; called by muse, mutect2, varscan2
- ACTL7B | c.855C>A p.D285E | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65926812, COSV65927618; called by muse, mutect2
- ADAM23 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52219279; called by muse, mutect2, varscan2
- ADAMTS16 | c.196T>A p.Y66N | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV56994602, COSV57010205; called by muse, mutect2, varscan2
- ADGRB1 | c.1349A>T p.E450V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV60098707; called by muse, mutect2, varscan2
- ADGRB3 | c.1780G>T p.G594* | Nonsense Mutation (SNP) | VAF 95/385 reads (25%) | catalogued as COSV65402313; called by muse, mutect2, varscan2
- ADGRG4 | c.504C>A p.S168R | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV54959755; called by muse, varscan2
- ADGRG7 | c.1576T>A p.C526S | Missense Mutation (SNP) | VAF 255/532 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56298151; called by muse, mutect2, varscan2
- ADGRV1 | c.7773A>T p.E2591D | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.593); catalogued as COSV67988247; called by muse, mutect2, varscan2
- AGBL4 | c.844T>A p.S282T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.348); catalogued as COSV61893771, COSV61893927; called by mutect2, varscan2
- AGTPBP1 | c.1639G>T p.A547S (on ENST00000357081 / NM_001330701.2; = p.A507S on NM_015239.2) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV61273191; called by muse, mutect2, varscan2
- AL645922.1 | c.122G>T p.W41L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.868); catalogued as COSV54961231; called by muse, mutect2, varscan2
- ANAPC1 | c.4953G>T p.L1651F | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV61977035, COSV61978484; called by muse, mutect2, varscan2
- ANKRD11 | c.1648A>G p.N550D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV56363482; called by muse, mutect2, varscan2
- ARHGAP33 | c.3188G>A p.G1063D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.208); catalogued as COSV50127806; called by muse, mutect2, varscan2
- ARSF | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV63839996, COSV63841355; called by muse, mutect2, varscan2
- ASTN2 | c.2231C>T p.A744V (on ENST00000313400 / NM_001365069.1; = p.A693V on NM_014010.5) | Missense Mutation (SNP) | VAF 102/294 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57789257; called by muse, mutect2, varscan2
- ATAD2 | c.931A>C p.K311Q | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV54882589; called by muse, mutect2, varscan2
- ATL2 | c.79A>C p.S27R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV60053357; called by muse, mutect2, varscan2
- ATP9A | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as COSV58768249; called by muse, mutect2, varscan2
- B3GNT2 | c.1144G>C p.E382Q | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as rs933504803, COSV57345041; called by muse, mutect2
- B4GALT4 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63296020; called by muse, mutect2, varscan2
- BAZ2A | c.4541A>T p.D1514V | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51638750; called by muse, mutect2, varscan2
- BCHE | c.1446T>A p.D482E | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs754736317, COSV52258276; called by muse, mutect2, varscan2
- BCL11A | c.1954T>G p.S652A (on ENST00000335712 / NM_001365609.1; = p.S686A on NM_018014.4) | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.123); catalogued as COSV59632801; called by muse, mutect2, varscan2
- BCR | c.1276G>T p.A426S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.048); catalogued as rs774792375, COSV59933086; called by muse, mutect2
- BLVRB | c.243C>T p.L81= | Splice Region (SNP) | VAF 3/8 reads (38%) | catalogued as COSV54569713; called by muse, mutect2
- BRINP3 | c.1280C>A p.T427K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV66517169; called by muse, mutect2, varscan2
- C11orf65 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765960977, COSV67597772; called by muse, mutect2, varscan2
- C15orf39 | c.2233C>A p.P745T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV62297129; called by muse, mutect2, varscan2
- C2orf16 | c.5272C>A p.H1758N | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62676589; called by mutect2, varscan2
- C8A | c.1742C>A p.T581K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV63484861; called by muse, mutect2, varscan2
- CC2D2A | c.4309G>C p.D1437H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67504191; called by muse, mutect2
- CCDC39 | c.154A>T p.I52F | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56486858; called by muse, mutect2, varscan2
- CDCA2 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57946655; called by muse, mutect2, varscan2
- CDCA2 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57946667; called by muse, mutect2
- CDH10 | c.891C>A p.D297E | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52569471, COSV52598934; called by muse, varscan2
- CDH12 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1279913932, COSV66416544; called by muse, mutect2, varscan2
- CDH18 | c.2219A>C p.Y740S | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV56932971; called by muse, mutect2, varscan2
- CDH18 | c.1823C>A p.S608* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as rs752455084, COSV56908049, COSV56926034; called by muse, mutect2, varscan2
- CDH7 | c.815del p.P272Qfs*6 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | catalogued as COSV100543111; called by mutect2, pindel, varscan2
- CDH9 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); catalogued as COSV50267939, COSV50312263; called by muse, mutect2, varscan2
- CDX2 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.305); catalogued as rs1210053674, COSV66829630; called by muse, mutect2, varscan2
- CENPQ | c.277A>T p.M93L | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59921499; called by muse, mutect2, varscan2
- CEP76 | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV50867329; called by muse, mutect2, varscan2
- CHD8 | c.6499G>T p.V2167F (on ENST00000646647 / NM_001170629.2; = p.V1888F on NM_020920.4) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs770593901, COSV63036490, COSV63037040; called by muse, varscan2
- CNTN6 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63177059, COSV63179690; called by muse, mutect2
- CNTNAP2 | c.1496G>C p.G499A | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV62204494; called by muse, mutect2, varscan2
- COL2A1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61531774; called by muse, mutect2, varscan2
- COL3A1 | c.3943T>A p.W1315R | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58591030; called by muse, mutect2, varscan2
- COLEC12 | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV68371539; called by muse, mutect2, varscan2
- COPA | c.2663T>C p.L888P | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV54104584; called by muse, mutect2, varscan2
- CREB5 | c.1099C>G p.R367G (on ENST00000357727 / NM_182898.4; = p.R360G on NM_004904.3) | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV63222931; called by muse, mutect2, varscan2
- CRMP1 | c.1473G>C p.L491F | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.09); catalogued as COSV61481182; called by muse, mutect2, varscan2
- CSMD3 | c.9655G>T p.G3219C (on ENST00000297405 / NM_001363185.1; = p.G3050C on NM_052900.3) | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52219293; called by muse, mutect2, varscan2
- CSRNP1 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV56188841; called by muse, mutect2, varscan2
- CWH43 | c.854T>C p.V285A | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV56940155; called by muse, mutect2, varscan2
- CYP11B1 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV52828279; called by muse, mutect2, varscan2
- DACH2 | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV64173177; called by muse, mutect2, varscan2
- DENND5A | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV60232054, COSV60234949; called by muse, mutect2, varscan2
- DGKG | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53967082; called by muse, mutect2, varscan2
- DLGAP5 | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55963789; called by muse, mutect2, varscan2
- DNAH11 | c.3002A>G p.N1001S | Missense Mutation (SNP) | VAF 78/326 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1468087350, COSV60962701; called by muse, mutect2, varscan2
- DNAJC6 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV54777101; called by muse, mutect2, varscan2
- DPYS | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as COSV60910115; called by muse, varscan2
- DTX1 | c.1703C>A p.T568N | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99922021; called by muse, varscan2
- E2F8 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762189735, COSV51464409; called by muse, mutect2, varscan2
- ECPAS | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 178/473 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1277311352, COSV52200495; called by muse, mutect2, varscan2
- EDEM3 | c.2563G>A p.A855T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs759438611, COSV58925477; called by muse, mutect2, varscan2
- EDNRB | c.431G>A p.W144* (on ENST00000377211 / NM_001201397.1; = p.W54* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 39/102 reads (38%) | catalogued as COSV57524654; called by muse, mutect2, varscan2
- EFL1 | c.3142G>C p.A1048P | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51606813; called by muse, mutect2, varscan2
- ELAPOR2 | c.2843A>T p.Y948F (on ENST00000450689 / NM_001142749.3; = p.Y781F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51888094; called by muse, mutect2, varscan2
- ELL2 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 233/402 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV52983182, COSV52983409; called by muse, mutect2, varscan2
- ENTPD8 | c.239T>G p.V80G | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58162476; called by muse, mutect2, varscan2
- EPB41L3 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV59458122; called by muse, mutect2, varscan2
- F11R | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as COSV57038423; called by muse, mutect2
- FAM43A | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV61673196; called by muse, mutect2, varscan2
- FAT2 | c.5053A>G p.M1685V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1025960339, COSV55822734; called by muse, mutect2, varscan2
- FAT4 | c.7181C>T p.S2394L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV58692400; called by muse, mutect2, varscan2
- FBL | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV55681616, COSV55683082; called by muse, mutect2, varscan2
- FBN3 | c.6295G>T p.V2099F | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.127); catalogued as COSV54464251, COSV99561273; called by muse, mutect2, varscan2
- FER1L5 | c.3863C>A p.S1288Y (on ENST00000623019; = p.S1261Y on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV67606478; called by muse, mutect2, varscan2
- FER1L6 | c.3488C>T p.S1163L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV67550861; called by muse, mutect2, varscan2
- FILIP1L | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs753432256, COSV58770958; called by muse, mutect2, varscan2
- FIZ1 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV55608170; called by muse, mutect2, varscan2
- FREM1 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66522799; called by muse, mutect2, varscan2
- FRRS1L | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73746672; called by muse, mutect2, varscan2
- FRYL | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51951169; called by muse, mutect2, varscan2
- GABRG3 | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100406212, COSV61522129; called by muse, mutect2, varscan2
- GAL3ST3 | c.147G>C p.L49F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs756891581, COSV61749192; called by muse, mutect2, varscan2
- GAPVD1 | c.3544C>G p.Q1182E (on ENST00000394104; = p.Q1191E on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV52924443; called by muse, mutect2
- GBA | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs747284798, CM065218, COSV59170183; called by muse, mutect2, varscan2
- GCNT1 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as COSV65057989; called by muse, mutect2, varscan2
- GCNT1 | c.932G>T p.W311L | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946472; called by muse, mutect2, varscan2
- GDA | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV52994524; called by muse, mutect2, varscan2
- GFM1 | c.2239G>T p.G747* | Nonsense Mutation (SNP) | VAF 14/264 reads (5%) | catalogued as COSV51833577; called by muse, mutect2
- GLI3 | c.2624G>T p.R875L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as CD107047, COSV67887589, COSV67890306; called by muse, mutect2, varscan2
- GLRX5 | c.444A>T p.L148F | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV58763670; called by muse, mutect2, varscan2
- GLUL | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV59382546; called by muse, mutect2, varscan2
- GOLGA8G | c.1406T>G p.M469R | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61551051; called by muse, mutect2, varscan2
- GP2 | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs144565957; called by muse, mutect2, varscan2
- GPR141 | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 67/237 reads (28%) | catalogued as rs373247764, COSV57733822, COSV57734309; called by muse, mutect2, varscan2
- GPR152 | c.82del p.Q28Kfs*22 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs757144127, COSV56887712; called by mutect2, pindel, varscan2
- GPR158 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as COSV66273550; called by muse, mutect2, varscan2
- GRIK3 | c.1544C>A p.A515D | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66141695; called by muse, mutect2, varscan2
- GRIP1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); catalogued as COSV54029030; called by muse, mutect2, varscan2
- HAS3 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54707659; called by muse, mutect2, varscan2
- HBD | c.54A>C p.K18N | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53082979; called by muse, mutect2, varscan2
- HERC5 | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52041270; called by muse, mutect2, varscan2
- HOXA1 | c.514G>T p.A172S | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as COSV56066897; called by muse, mutect2, varscan2
- HOXD10 | c.856T>A p.L286M | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50892832; called by muse, mutect2, varscan2
- HSD3B2 | c.247T>C p.C83R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV65593494; called by muse, mutect2, varscan2
- IFI27 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54141027; called by muse, mutect2, varscan2
- IFT52 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); catalogued as COSV65975374; called by muse, mutect2, varscan2
- IGF2R | c.7394G>C p.S2465T | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63630134; called by muse, mutect2, varscan2
- IGSF22 | c.1903C>A p.P635T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.596); catalogued as COSV60030905, COSV60035597; called by muse, mutect2
- IRAK3 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs865990467, COSV54162721; called by muse, mutect2, varscan2
- IRS1 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59337466; called by muse, mutect2, varscan2
- IRS1 | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59337472; called by muse, mutect2, varscan2
- IRX1 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV57359497, COSV57360320; called by muse, mutect2, varscan2
- JAKMIP2 | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV54607699, COSV54617022; called by muse, mutect2, varscan2
- JCAD | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as COSV64760308; called by muse, mutect2, varscan2
- KAT14 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66606807, COSV66608172; called by muse, mutect2, varscan2
- KCND2 | c.605A>T p.N202I | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV58586834; called by muse, mutect2, varscan2
- KCNH7 | c.908T>A p.V303D | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.091); catalogued as COSV59801003; called by muse, mutect2, varscan2
- KCNQ1 | c.530C>A p.S177Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50114177; called by muse, mutect2, varscan2
- KCNS1 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60260362; called by muse, mutect2, varscan2
- KIF2B | c.1155A>T p.Q385H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV52132143; called by muse, mutect2, varscan2
- KLHL1 | c.1950T>G p.Y650* | Nonsense Mutation (SNP) | VAF 49/126 reads (39%) | catalogued as COSV64775021; called by muse, mutect2, varscan2
- KLHL42 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.081); catalogued as COSV67145970; called by muse, mutect2, varscan2
- KRTAP10-6 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 61/263 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.024); catalogued as COSV59967485, COSV59976661; called by muse, mutect2, varscan2
- KRTAP13-4 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as COSV61879580; called by muse, mutect2, varscan2
- LAMP1 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV58150617; called by muse, varscan2
- LANCL1 | c.1153G>T p.D385Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52065663; called by muse, mutect2, varscan2
- LBR | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55289691; called by muse, mutect2, varscan2
- LDLRAD4 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV63338931; called by muse, mutect2, varscan2
- LEPR | c.1390T>A p.L464M | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60757625; called by muse, mutect2, varscan2
- LHCGR | c.1930T>G p.C644G | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54298843; called by muse, mutect2, varscan2
- LHCGR | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV54292936; called by muse, varscan2
- LRP1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV54515838; called by muse, mutect2, varscan2
- LRP1 | c.11542A>T p.S3848C | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV54515848; called by muse, mutect2, varscan2
- LRRC43 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as rs764289368, COSV60287836; called by muse, mutect2, varscan2
- LRRC4C | c.1502C>A p.T501K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as COSV53429498; called by muse, mutect2, varscan2
- LRRC4C | c.753A>G p.I251M | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758646539, COSV53429510; called by muse, mutect2, varscan2
- LRRN3 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as rs1167488652, COSV57821148; called by muse, mutect2, varscan2
- MAGEB4 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66775961; called by muse, mutect2, varscan2
- MANEAL | c.1327C>T p.R443C (on ENST00000373045 / NM_001113482.1; = p.R221C on NM_152496.2) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs758750496, COSV61116293; called by muse, mutect2, varscan2
- MBNL2 | c.366A>G p.I122M | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59122500; called by muse, mutect2, varscan2
- MC1R | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1242179882, COSV59625831; called by muse, mutect2, varscan2
- MDGA2 | c.2872A>G p.T958A (on ENST00000399232 / NM_001113498.2; = p.T660A on NM_182830.4) | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV62098949; called by muse, mutect2, varscan2
- MDN1 | c.6802A>T p.S2268C | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV65523812; called by muse, mutect2, varscan2
- MFSD2B | c.443T>A p.F148Y | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV57855167; called by muse, mutect2, varscan2
- MIIP | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV52427947; called by muse, mutect2, varscan2
- MME | c.1780+2T>A p.X594_splice | Splice Site (SNP) | VAF 37/224 reads (17%) | catalogued as COSV100852240, COSV64708303; called by muse, mutect2, varscan2
- MOCS1 | c.644A>T p.K215M | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57937310; called by muse, mutect2, varscan2
- MPIG6B | c.575T>A p.V192E (on ENST00000649779 / NM_138272.3; = p.S198R on NM_025260.4) | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV65389844; called by muse, mutect2, varscan2
- MYH7 | c.298G>T p.A100S | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.95); PolyPhen benign (0.215); catalogued as rs730880154, CM1212403, COSV62520732, COSV62522404; called by muse, mutect2, varscan2
- MYO15A | c.5913G>A p.L1971= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as COSV52759384; called by muse, mutect2, varscan2
- MYOM2 | c.2709G>T p.E903D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.69); catalogued as COSV50727301; called by muse, mutect2, varscan2
- NCAN | c.2840G>C p.G947A | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV53053227; called by muse, mutect2, varscan2
- NEK5 | c.1942G>T p.V648L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV62880548; called by muse, mutect2, varscan2
- NFYA | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.151); catalogued as COSV58199025; called by muse, mutect2, varscan2
- NKAPL | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59198273; called by muse, mutect2
- NLGN1 | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 91/384 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV64330956, COSV64337747; called by muse, mutect2, varscan2
- NLGN1 | c.511G>C p.G171R | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV64337758; called by muse, mutect2
- NLRP10 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV60779909, COSV60780884; called by muse, mutect2, varscan2
- NLRP12 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs778688033, COSV60746013; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOTCH1 | c.7081C>T p.Q2361* | Nonsense Mutation (SNP) | VAF 34/233 reads (15%) | catalogued as COSV53062827; called by muse, mutect2, varscan2
- NOX4 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV54456229; called by muse, varscan2
- NPAS2 | c.786A>C p.L262F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59559050; called by muse, varscan2
- NPBWR1 | c.54C>A p.D18E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58696673; called by muse, mutect2, varscan2
- NR4A2 | c.1597A>C p.N533H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV59894374; called by muse, mutect2, varscan2
- NT5DC3 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67322058; called by muse, mutect2, varscan2
- NTN5 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54307693; called by muse, mutect2, varscan2
- OBSCN | c.12121G>C p.E4041Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52787973; called by muse, mutect2
- OR10J3 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV100171863, COSV99046061; called by muse, mutect2, varscan2
- OR10R2 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV63769013; called by muse, mutect2
- OR10T2 | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV57781958; called by muse, mutect2, varscan2
- OR11H12 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV101612523, COSV73569284; called by mutect2, varscan2
- OR13F1 | c.625A>T p.M209L | Missense Mutation (SNP) | VAF 131/482 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58250733, COSV58251891; called by muse, mutect2, varscan2
- OR2A5 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV101278665, COSV68738867; called by muse, mutect2, varscan2
- OR2G3 | c.917C>A p.S306* | Nonsense Mutation (SNP) | VAF 55/134 reads (41%) | catalogued as COSV100180524, COSV60680937, COSV60682135; called by muse, mutect2, varscan2
- OR2M3 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs763678991, COSV71759110; called by muse, mutect2, varscan2
- OR2T1 | c.931del p.Q311Kfs*34 | Frame Shift Del (DEL) | VAF 81/278 reads (29%) | catalogued as COSV100822344; called by mutect2, pindel, varscan2
- OR2T3 | c.232T>C p.Y78H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100613386; called by muse, mutect2, varscan2
- OR4L1 | c.716C>A p.T239K | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59849311, COSV59850362; called by muse, mutect2
- OR4N2 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60052465; called by muse, mutect2, varscan2
- OR4N2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 64/226 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs368630542, COSV60050638; called by muse, mutect2, varscan2
- OR51F1 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as COSV58580103; called by muse, mutect2
- OR5H14 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 52/479 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV71193607; called by muse, mutect2, varscan2
- OR5K1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV60304432; called by muse, mutect2, varscan2
- OR5W2 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV60614690, COSV60616732, COSV60618306; called by muse, mutect2, varscan2
- OR9G1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.874); catalogued as rs770002947, COSV56451568; called by muse, mutect2, varscan2
- OR9Q1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV59042189; called by muse, mutect2, varscan2
- OSBPL6 | c.2251A>T p.I751F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51921318; called by muse, mutect2, varscan2
- OTOGL | c.4333G>C p.V1445L (on ENST00000547103; = p.V1436L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101509487; called by muse, mutect2, varscan2
- PCDHA6 | c.968C>G p.T323R | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.048); catalogued as COSV100972215, COSV100972507; called by muse, mutect2, varscan2
- PCDHB13 | c.2129C>A p.A710E | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV53396195, COSV53401475; called by muse, mutect2, varscan2
- PCDHB3 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50583983; called by muse, mutect2, varscan2
- PCLO | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs752862200, COSV61643890; called by muse, mutect2, varscan2
- PDE3B | c.979-2A>G p.X327_splice | Splice Site (SNP) | VAF 22/83 reads (27%) | catalogued as COSV56385763; called by muse, mutect2, varscan2
- PDK4 | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50011371; called by muse, mutect2, varscan2
- PITPNM3 | c.802G>T p.G268W | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52596781; called by muse, mutect2, varscan2
- PKN1 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs781056624, COSV54399436; called by muse, mutect2, varscan2
- PLA2G5 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV64283122; called by muse, mutect2, varscan2
- PLAAT1 | c.677A>G p.H226R (on ENST00000650797; = p.H121R on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/179 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53231895; called by muse, mutect2, varscan2
- PLCE1 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV53356872; called by muse, mutect2, varscan2
- PLCL1 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV70828931, COSV70877283; called by muse, mutect2, varscan2
- POP1 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761103255, COSV62893205; called by muse, mutect2, varscan2
- PPP2R1A | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV59045712; called by muse, mutect2, varscan2
- PRB1 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV99072789; called by muse, varscan2
- PRG2 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs758760583, COSV61293737; called by muse, mutect2, varscan2
- PRKD1 | c.524T>A p.L175H | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59574121; called by muse, mutect2, varscan2
- PRL | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.104); catalogued as COSV60592693; called by muse, mutect2, varscan2
- PRTG | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV101221280, COSV66838704; called by muse, mutect2, varscan2
- PRUNE2 | c.7451A>G p.D2484G | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV65043152; called by muse, mutect2, varscan2
- PTPRH | c.1374A>C p.E458D | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs1298405504, COSV54746791; called by muse, mutect2, varscan2
- PXDNL | c.2896G>T p.A966S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV62491002; called by muse, mutect2
- QSER1 | c.3251A>G p.E1084G (on ENST00000399302; = p.E1213G on NM_001076786.3) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs1380586391, COSV67901016; called by muse, mutect2, varscan2
- RAB38 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV54713739; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52966304; called by muse, mutect2, varscan2
- RAG1 | c.1922T>G p.V641G | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55026054; called by muse, mutect2, varscan2
- RAI1 | c.3515G>T p.R1172L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV55394644; called by muse, mutect2, varscan2
- RALA | c.348A>T p.E116D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50049512; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as COSV52788468; called by muse, mutect2, varscan2
- RARG | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58433446; called by muse, mutect2, varscan2
- RASD2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53352812; called by muse, mutect2, varscan2
- RASGRP3 | c.653G>T p.R218M | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67822863; called by muse, mutect2, varscan2
- RBFOX2 | c.708G>T p.R236S (on ENST00000438146 / NM_001349995.2; = p.R166S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV53265676; called by muse, mutect2, varscan2
- RBM27 | c.2587A>G p.M863V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV54591216; called by muse, mutect2, varscan2
- RBMXL2 | c.1127del p.G376Efs*4 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as COSV60982312; called by mutect2, pindel, varscan2
- REG3A | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 29/120 reads (24%) | catalogued as COSV59410149, COSV59410240; called by muse, varscan2
- REG3A | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59410156; called by muse, varscan2
- REG3A | c.101C>G p.P34R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV59409626, COSV59410163; called by muse, mutect2, varscan2
- RETNLB | c.97A>T p.K33* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV55465786; called by muse, mutect2, varscan2
- RHOBTB1 | c.932G>T p.C311F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.218); catalogued as COSV61959082; called by muse, mutect2, varscan2
- RIC3 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1208557008, COSV58302765; called by muse, mutect2, varscan2
- ROBO4 | c.1939A>C p.K647Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.527); catalogued as COSV60625320; called by muse, mutect2, varscan2
- ROS1 | c.6430G>A p.V2144I | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs749189360, COSV63856862; called by muse, mutect2, varscan2
- RRM1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV100331219; called by muse, varscan2
- RUNX1T1 | c.955A>T p.S319C (on ENST00000265814 / NM_001198628.1; = p.S292C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV56151609; called by muse, mutect2, varscan2
- RYR3 | c.300C>A p.H100Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66796070; called by muse, mutect2, varscan2
- RYR3 | c.8618A>T p.H2873L (on ENST00000389232; = p.H2874L on NM_001036.6) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66796081; called by muse, mutect2, varscan2
- SAMSN1 | c.389A>G p.Y130C | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1339852064, COSV53473189; called by muse, mutect2, varscan2
- SATB2 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53486685; called by muse, mutect2, varscan2
- SCMH1 | c.607G>C p.G203R (on ENST00000326197 / NM_001031694.2; = p.G156R on NM_012236.4) | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58236692; called by muse, mutect2, varscan2
- SCN4A | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); catalogued as COSV71127449, COSV71127561; called by muse, mutect2, varscan2
- SELL | c.1036C>A p.P346T (on ENST00000650983; = p.P333T on NM_000655.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52552703; called by muse, mutect2
- SHC3 | c.1500C>G p.Y500* | Nonsense Mutation (SNP) | VAF 60/565 reads (11%) | catalogued as COSV65439147; called by muse, mutect2, varscan2
- SHISA4 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV62884642; called by muse, mutect2, varscan2
- SIPA1L2 | c.4354G>C p.D1452H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1366197830, COSV53392911, COSV53398082; called by muse, mutect2, varscan2
- SLC22A16 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57931172; called by muse, mutect2, varscan2
- SLC24A4 | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV54115402; called by muse, mutect2, varscan2
- SLC30A8 | c.595A>T p.R199* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV69972365; called by muse, mutect2, varscan2
- SLC4A11 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.107); catalogued as COSV66262455; called by muse, mutect2, varscan2
- SLC4A8 | c.1838T>A p.L613Q | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV60654665; called by muse, mutect2, varscan2
- SLCO2B1 | c.1129G>T p.V377F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56936296; called by muse, mutect2
- SMPD3 | c.1520T>C p.V507A | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV54713391; called by muse, mutect2, varscan2
- SP5 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64623425; called by muse, mutect2, varscan2
- SPATA31A1 | c.2000del p.P667Rfs*20 | Frame Shift Del (DEL) | VAF 96/979 reads (10%) | catalogued as COSV66533531; called by mutect2, pindel
- SPIRE2 | c.727-2A>T p.X243_splice | Splice Site (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65556427; called by muse, mutect2
- SPIRE2 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV65556439; called by muse, mutect2
- SYNE1 | c.7780G>T p.E2594* (on ENST00000367255 / NM_182961.4; = p.E2601* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 23/124 reads (19%) | catalogued as COSV55017555; called by muse, mutect2, varscan2
- SYTL5 | c.905G>C p.R302P | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.38); catalogued as COSV52902389; called by muse, mutect2, varscan2
- TGFBR2 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 40/95 reads (42%) | catalogued as COSV55452477; called by muse, mutect2, varscan2
- TGFBR3 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.724); catalogued as COSV53027409; called by muse, mutect2, varscan2
- TMEM100 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV70118110; called by muse, mutect2, varscan2
- TMEM234 | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV59084762; called by muse, mutect2
- TNFSF18 | c.192T>A p.S64R | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.276); catalogued as COSV53440822; called by muse, mutect2, varscan2
- TOPBP1 | c.3227A>T p.Q1076L | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53437540; called by muse, mutect2
- TP53 | c.142del p.D48Tfs*75 | Frame Shift Del (DEL) | VAF 168/366 reads (46%) | catalogued as CD114001, COSV52987957, COSV53821134; called by mutect2, pindel, varscan2
- TRAF6 | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 187/455 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV61922788; called by muse, mutect2, varscan2
- TRPC1 | c.856C>G p.L286V (on ENST00000476941 / NM_001251845.2; = p.L252V on NM_003304.4) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56426693; called by muse, mutect2, varscan2
- TSNARE1 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV56178079; called by muse, mutect2, varscan2
- TTN | c.10283C>T p.T3428I (on ENST00000591111; = p.T3382I on NM_003319.4) | Missense Mutation (SNP) | VAF 53/167 reads (32%) | PolyPhen possibly damaging (0.827); catalogued as COSV60149873; called by muse, mutect2, varscan2
- TTN | c.8038G>T p.A2680S (on ENST00000591111; = p.A2634S on NM_003319.4) | Missense Mutation (SNP) | VAF 24/107 reads (22%) | PolyPhen benign (0.005); catalogued as COSV59951704; called by muse, mutect2, varscan2
- TYR | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV54478982; called by muse, mutect2
- UNC93A | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV57809139; called by muse, mutect2, varscan2
- USH2A | c.7066A>T p.N2356Y | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV56389025; called by muse, mutect2, varscan2
- USH2A | c.5131G>A p.A1711T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535796173, COSV56389041; called by muse, mutect2, varscan2
- USHBP1 | c.722G>T p.S241I | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53104370; called by muse, mutect2, varscan2
- USP29 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 23/105 reads (22%) | catalogued as COSV54240849, COSV54242182; called by muse, mutect2, varscan2
- USP34 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as COSV101277197, COSV68402748; called by muse, mutect2, varscan2
- UTP20 | c.4578G>C p.L1526F | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55376604; called by muse, mutect2, varscan2
- XDH | c.3443G>T p.G1148V | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65147749, COSV65149604; called by muse, mutect2, varscan2
- XIRP2 | c.8687A>G p.E2896G (on ENST00000628543; = p.E3071G on NM_152381.6) | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); catalogued as COSV54710573; called by muse, mutect2, varscan2
- ZBTB7B | c.1198C>T p.R400C (on ENST00000292176; = p.R434C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs766949384, COSV52693356; called by muse, mutect2, varscan2
- ZC3H7B | c.2795A>T p.K932M | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60962851; called by muse, mutect2, varscan2
- ZC4H2 | c.551C>A p.P184Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62004403; called by muse, mutect2, varscan2
- ZEB1 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58047520; called by muse, mutect2, varscan2
- ZNF17 | c.1157A>T p.Y386F | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV56921743; called by muse, mutect2, varscan2
- ZNF208 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.497); catalogued as COSV68108576; called by muse, mutect2, varscan2
- ZNF33B | c.101G>T p.R34M | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV63942253; called by muse, mutect2, varscan2
- ZNF385B | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750056621, COSV61178809; called by muse, mutect2, varscan2
- ZNF441 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV63540118; called by muse, mutect2, varscan2
- ZNF536 | c.480C>A p.C160* | Nonsense Mutation (SNP) | VAF 26/94 reads (28%) | catalogued as COSV62826934; called by muse, mutect2, varscan2
- ZNF557 | c.115G>C p.E39Q (on ENST00000414706 / NM_001044388.2; = p.E46Q on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.106); catalogued as COSV53274319; called by muse, mutect2, varscan2
- ZNF780A | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 85/370 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.985); catalogued as rs751047796, COSV61815736; called by muse, mutect2, varscan2
- ZNHIT6 | c.1196C>T p.T399I | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV65326557, COSV65327235; called by muse, mutect2, varscan2
- ZP2 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99559776; called by muse, mutect2, varscan2
- CHTF18 | c.1684dup p.R562Pfs*52 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- GLI2 | c.3706del p.Q1236Sfs*2 (on ENST00000361492 / NM_001374353.1; = p.Q1253Sfs*2 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, varscan2
- HNMT | c.202_209del p.L68Sfs*16 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- HOOK3 | c.974del p.K325Rfs*3 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ITPR3 | c.6260C>G p.S2087C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- LCN9 | c.528del p.W176Cfs*? | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | called by mutect2, pindel, varscan2
- MIOS | c.1751del p.N584Ifs*12 | Frame Shift Del (DEL) | VAF 79/297 reads (27%) | called by mutect2, pindel, varscan2
- MYH15 | c.2546del p.K849Sfs*9 | Frame Shift Del (DEL) | VAF 24/159 reads (15%) | called by mutect2, varscan2
- NUP214 | c.3779del p.G1260Efs*98 | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | called by mutect2, pindel, varscan2
- OR4A47 | c.507dup p.N170Qfs*4 | Frame Shift Ins (INS) | VAF 77/232 reads (33%) | called by mutect2, pindel, varscan2
- OR4K13 | c.533dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 29/145 reads (20%) | called by mutect2, pindel, varscan2
- POTEA | c.1271C>G p.S424* (on ENST00000519951 / NM_001005365.2; = p.S378* on NM_001002920.1) | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- RGS9BP | c.111del p.Q38Rfs*21 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel
- SPATA31A1 | c.1402C>A p.Q468K | Missense Mutation (SNP) | VAF 295/1648 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- SPIB | c.152del p.P51Hfs*129 | Frame Shift Del (DEL) | VAF 26/123 reads (21%) | called by mutect2, pindel, varscan2
- TINAG | c.1296+1del | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- TMEM131 | c.4396dup p.S1466Kfs*8 | Frame Shift Ins (INS) | VAF 34/169 reads (20%) | called by mutect2, pindel, varscan2
- TTN | c.20140del p.C6714Afs*20 (on ENST00000591111; = p.C5787Afs*20 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- ZNF460 | c.273dup p.Q92Afs*10 | Frame Shift Ins (INS) | VAF 29/141 reads (21%) | called by mutect2, pindel, varscan2
- ZNF658 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 148/539 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ABCA7 | c.5388G>A p.R1796= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV54032166; called by muse, mutect2, varscan2
- ADGRV1 | c.7974C>A p.T2658= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV67988250; called by muse, mutect2, varscan2
- AP2B1 | c.2328G>A p.L776= | Silent (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.153G>A p.K51= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV54503315; called by muse, mutect2, varscan2
- ASTN2 | c.1080C>G p.R360= | Silent (SNP) | VAF 37/163 reads (23%) | catalogued as COSV57789271; called by muse, mutect2, varscan2
- ATP23 | c.267A>G p.E89= | Silent (SNP) | VAF 74/234 reads (32%) | catalogued as COSV55686216; called by muse, mutect2, varscan2
- BAZ1B | c.576C>T p.D192= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV59992145; called by muse, mutect2, varscan2
- BEND4 | c.1284T>A p.L428= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV72469182; called by muse, mutect2, varscan2
- BMP6 | c.1185G>C p.A395= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as COSV51660277, COSV51667280; called by muse, mutect2, varscan2
- CCNH | c.834G>A p.E278= | Silent (SNP) | VAF 89/243 reads (37%) | catalogued as COSV56925358; called by muse, mutect2, varscan2
- CD163 | c.1539C>T p.S513= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs370456843; called by muse, mutect2, varscan2
- CD1D | c.111C>T p.A37= | Silent (SNP) | VAF 64/691 reads (9%) | catalogued as COSV63809314; called by muse, mutect2
- CDH10 | c.957C>A p.I319= | Silent (SNP) | VAF 65/304 reads (21%) | catalogued as rs1462376539, COSV52582557, COSV52585396; called by muse, varscan2
- CDH8 | c.915T>A p.I305= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV54876191; called by muse, mutect2, varscan2
- CDK12 | c.2841G>A p.L947= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as rs937018559, COSV71001323; called by muse, mutect2, varscan2
- COL27A1 | c.111C>G p.A37= | Silent (SNP) | VAF 107/295 reads (36%) | catalogued as COSV61927641; called by muse, mutect2, varscan2
- COPA | c.2664C>T p.L888= | Silent (SNP) | VAF 95/181 reads (52%) | catalogued as COSV54104558; called by muse, mutect2, varscan2
- CPS1 | c.1446C>G p.V482= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV51814343; called by muse, mutect2, varscan2
- CREB5 | c.993A>T p.P331= (on ENST00000357727 / NM_182898.4; = p.P324= on NM_004904.3) | Silent (SNP) | VAF 58/267 reads (22%) | catalogued as COSV63222924; called by muse, mutect2, varscan2
- CYP2F1 | c.585G>T p.L195= | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as COSV58527981; called by muse, mutect2, varscan2
- DAPK3 | c.1317C>T p.R439= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1473439253, COSV56663526; called by muse, mutect2, varscan2
- DOCK4 | c.2067C>A p.I689= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV70239073; called by muse, mutect2, varscan2
- DYSF | c.951C>T p.L317= | Silent (SNP) | VAF 34/167 reads (20%) | catalogued as COSV50455140; called by muse, mutect2, varscan2
- ERICH3 | c.4371A>T p.A1457= | Silent (SNP) | VAF 66/245 reads (27%) | catalogued as COSV58610305; called by muse, mutect2, varscan2
- ERICH3 | c.2904C>T p.D968= | Silent (SNP) | VAF 52/186 reads (28%) | catalogued as rs373308732; called by muse, mutect2, varscan2
- EXD3 | c.1380G>A p.K460= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs1427821168, COSV59808745; called by muse, mutect2, varscan2
- GLB1L2 | c.717G>A p.K239= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as COSV60279221; called by muse, mutect2, varscan2
- GPI | c.1287C>T p.F429= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV62893440, COSV62893659, COSV62894277; called by muse, mutect2, varscan2
- GPR148 | c.942C>T p.A314= | Silent (SNP) | VAF 38/109 reads (35%) | catalogued as COSV59308631; called by muse, mutect2, varscan2
- GPR55 | c.405C>A p.P135= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV67408000; called by muse, mutect2, varscan2
- GPRC6A | c.165C>A p.P55= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as COSV59953812; called by muse, mutect2, varscan2
- HOXA1 | c.513G>T p.L171= | Silent (SNP) | VAF 53/218 reads (24%) | catalogued as COSV56066903; called by muse, mutect2, varscan2
- HOXD3 | c.951G>T p.A317= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1338340847, COSV50881876, COSV50884859; called by muse, mutect2, varscan2
- IL9 | c.78G>A p.G26= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as COSV50853528; called by muse, mutect2, varscan2
- IMPG1 | c.201A>T p.R67= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV64059076; called by muse, mutect2, varscan2
- IQCJ | c.330C>A p.I110= | Silent (SNP) | VAF 78/430 reads (18%) | catalogued as COSV67333810; called by muse, mutect2, varscan2
- IREB2 | c.720G>A p.K240= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV51924022, COSV99358995; called by muse, mutect2, varscan2
- IRX4 | c.324G>T p.S108= | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as COSV99181384; called by muse, mutect2, varscan2
- KCNH7 | c.216C>T p.P72= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs374582778, COSV59801010; called by muse, mutect2, varscan2
- KDM4B | c.768C>T p.I256= | Silent (SNP) | VAF 88/235 reads (37%) | catalogued as COSV50228039; called by muse, mutect2, varscan2
- KIFAP3 | c.1080G>A p.L360= | Silent (SNP) | VAF 48/229 reads (21%) | catalogued as COSV63034920; called by muse, mutect2, varscan2
- LENG9 | c.705C>T p.A235= | Silent (SNP) | VAF 44/147 reads (30%) | catalogued as rs1259617136, COSV56618783; called by muse, mutect2, varscan2
- LILRA6 | c.1314A>G p.S438= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV54438983; called by muse, mutect2, varscan2
- MRPS5 | c.720G>T p.S240= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV55533954; called by muse, mutect2, varscan2
- MSR1 | c.483C>A p.T161= | Silent (SNP) | VAF 43/198 reads (22%) | catalogued as rs533140719, COSV50511338; called by muse, mutect2, varscan2
- MTA3 | c.1374A>G p.P458= | Silent (SNP) | VAF 70/236 reads (30%) | catalogued as COSV63196925; called by muse, mutect2, varscan2
- MTMR4 | c.807G>T p.G269= | Silent (SNP) | VAF 15/114 reads (13%) | catalogued as COSV100051380; called by muse, mutect2, varscan2
- MYOD1 | c.366G>A p.L122= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV51454171; called by muse, mutect2, varscan2
- NHS | c.4824C>A p.I1608= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV66277405; called by muse, mutect2, varscan2
- NLGN1 | c.69G>T p.R23= | Silent (SNP) | VAF 91/381 reads (24%) | catalogued as rs773646291, COSV64337753; called by muse, mutect2, varscan2
- NR4A3 | c.1377T>A p.T459= | Silent (SNP) | VAF 31/98 reads (32%) | catalogued as rs529277354, COSV58246084; called by muse, mutect2, varscan2
- OPLAH | c.3588C>T p.T1196= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs781785809, COSV66299200; called by muse, mutect2, varscan2
- OR10S1 | c.618C>A p.T206= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV73342863; called by muse, mutect2, varscan2
- OR13F1 | c.624C>A p.P208= | Silent (SNP) | VAF 122/470 reads (26%) | catalogued as COSV58251880; called by muse, varscan2
- OR13J1 | c.309G>A p.L103= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as rs1350052814, COSV65069963; called by muse, mutect2, varscan2
- OR14K1 | c.315G>T p.L105= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV99315432; called by muse, mutect2, varscan2
- OR2G3 | c.402C>A p.V134= | Silent (SNP) | VAF 37/217 reads (17%) | catalogued as COSV60682131; called by muse, mutect2, varscan2
- OR4L1 | c.714C>A p.S238= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV59850354; called by muse, mutect2
- OR4X1 | c.645C>A p.S215= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV60723208; called by muse, mutect2, varscan2
- OR52B4 | c.108C>G p.S36= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV101281613, COSV68769149; called by muse, mutect2, varscan2
- OR5W2 | c.276A>T p.I92= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100747676, COSV60616744; called by muse, mutect2, varscan2
- OR6B1 | c.618C>T p.I206= | Silent (SNP) | VAF 59/239 reads (25%) | catalogued as COSV101281629, COSV68770307; called by muse, mutect2, varscan2
- PCDH9 | c.3240C>A p.I1080= (on ENST00000377865 / NM_203487.3; = p.I1046= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/101 reads (45%) | catalogued as COSV60562041; called by muse, mutect2, varscan2
- PDE8B | c.1941A>T p.A647= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV53739702; called by muse, mutect2, varscan2
- PLXNA3 | c.192G>T p.R64= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV63754516; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1182C>A p.S394= (on ENST00000611850; = p.S395= on NM_005396.5) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV53944547; called by muse, mutect2
- POLQ | c.5364G>T p.G1788= | Silent (SNP) | VAF 27/190 reads (14%) | catalogued as rs1236594830, COSV51754689; called by muse, mutect2, varscan2
- PTK7 | c.2172C>T p.F724= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV57849454; called by muse, mutect2, varscan2
- RASAL3 | c.501C>A p.S167= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV59140120; called by muse, varscan2
- RHOQ | c.447G>A p.Q149= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV53190545; called by muse, mutect2, varscan2
- RPL4 | c.921G>A p.K307= | Silent (SNP) | VAF 43/135 reads (32%) | catalogued as COSV57181111; called by muse, mutect2, varscan2
- SLCO6A1 | c.1293A>T p.P431= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV65811700; called by muse, mutect2, varscan2
- SLITRK3 | c.2892G>T p.P964= | Silent (SNP) | VAF 45/586 reads (8%) | catalogued as COSV53850899, COSV99578396; called by muse, mutect2
- SNED1 | c.1293C>T p.D431= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs917047011, COSV100123314; called by muse, mutect2
- SPR | c.765C>T p.H255= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs755370519, COSV52298074; called by muse, mutect2, varscan2
- SUPT6H | c.1755A>G p.L585= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV58928594; called by muse, mutect2, varscan2
- TAS2R7 | c.189A>G p.L63= | Silent (SNP) | VAF 72/205 reads (35%) | catalogued as COSV53689295; called by muse, mutect2, varscan2
- TBX10 | c.174G>A p.K58= | Silent (SNP) | VAF 34/133 reads (26%) | catalogued as COSV59008253; called by muse, mutect2, varscan2
- TEKT4 | c.15G>T p.V5= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1315967125, COSV54625932; called by muse, mutect2
- TSEN34 | c.549C>A p.L183= | Silent (SNP) | VAF 61/246 reads (25%) | catalogued as COSV55476367; called by muse, mutect2, varscan2
- WDR33 | c.3159G>T p.P1053= | Silent (SNP) | VAF 69/233 reads (30%) | catalogued as COSV59251067; called by muse, mutect2, varscan2
- WDR72 | c.420T>C p.D140= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV64749075; called by muse, mutect2, varscan2
- YPEL1 | c.36G>A p.A12= | Silent (SNP) | VAF 62/294 reads (21%) | catalogued as rs751203740, COSV59757214; called by mutect2, varscan2
- ZNF567 | c.1374C>T p.F458= (on ENST00000536254 / NM_001322913.1; = p.F427= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV62445813; called by muse, mutect2, varscan2
- ZNF800 | c.81A>T p.G27= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as COSV56177559; called by muse, mutect2, varscan2
- ZNF831 | c.453C>A p.R151= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as COSV64038516, COSV64041752; called by muse, mutect2, varscan2
- ZNF99 | c.1563C>T p.F521= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs543969115, COSV68056002; called by muse, mutect2, varscan2
- ANKMY1 | c.-122+576G>C | Intron (SNP) | VAF 28/143 reads (20%) | catalogued as COSV99803054; called by muse, mutect2, varscan2
- CDKL1 | c.171+5541A>G | Intron (SNP) | VAF 61/211 reads (29%) | catalogued as COSV53580496; called by muse, mutect2, varscan2
- CFLAR | c.1305-777G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100009826; called by muse, mutect2, varscan2
- FAM74A3 | n.357A>T | RNA (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- FGFR3 | c.*1200A>T | 3'UTR (SNP) | VAF 15/62 reads (24%) | catalogued as COSV53406424; called by muse, mutect2, varscan2
- HERC2P3 | n.64T>A | RNA (SNP) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- HM13 | c.1035-913G>C | Intron (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100159736; called by muse, mutect2, varscan2
- LBHD1 | c.617-502C>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100649249; called by muse, mutect2
- NXF5 | n.639T>G | RNA (SNP) | VAF 57/117 reads (49%) | catalogued as COSV53791716; called by muse, mutect2, varscan2
- OR5A2 | c.-2C>A | 5'UTR (SNP) | VAF 54/195 reads (28%) | catalogued as COSV100119833; called by muse, mutect2, varscan2
- OTUD6A | c.-2T>A | 5'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100611064; called by muse, mutect2, varscan2
- PTPRN2 | c.2783+2249A>G | Intron (SNP) | VAF 52/167 reads (31%) | catalogued as COSV66104850; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-20208T>A | Intron (SNP) | VAF 14/57 reads (25%) | catalogued as COSV67445639; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1789A>G | Intron (SNP) | VAF 59/144 reads (41%) | catalogued as COSV100678771; called by muse, mutect2, varscan2
- TRNAU1AP | chr1:28580381 C>T | 3'Flank (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- TTN | c.10360+1942G>C | Intron (SNP) | VAF 40/135 reads (30%) | catalogued as COSV60149859; called by muse, mutect2, varscan2
- TTN | c.10360+1129C>A | Intron (SNP) | VAF 110/443 reads (25%) | catalogued as COSV60149865, COSV60172811; called by muse, mutect2, varscan2
- XIRP2 | c.*65G>T | 3'UTR (SNP) | VAF 13/89 reads (15%) | catalogued as COSV99740781, COSV99746651; called by muse, varscan2
- XIRP2 | c.*66G>T | 3'UTR (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99746652; called by muse, mutect2, varscan2
- XIRP2 | c.*469G>T | 3'UTR (SNP) | VAF 30/123 reads (24%) | catalogued as rs747917850, COSV99746654; called by muse, mutect2, varscan2
- ZNF493 | c.-132+8561G>T | Intron (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100372042; called by muse, mutect2, varscan2
